Somatic mutation profile of tumor specimen HCM-CSHL-0090-C25-01A (aliquot HCM-CSHL-0090-C25-01A-11D-A77E-36) from HCMI case HCM-CSHL-0090-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 64.8 years (23,666 days).
Specimen HCM-CSHL-0090-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b762baa6-f35d-4bde-a9fa-5adcb204f5b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0090-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0090-C25-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/192621c3-b43f-47da-ad60-da63afb0d8b8

The open-access MAF lists 67 somatic variants for this specimen: 45 protein-altering or splice-affecting, 11 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 11, Frame Shift Del 4, 3'Flank 3, 5'UTR 2, 5'Flank 2, Intron 2, RNA 1, Frame Shift Ins 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 139/325 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CA1 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 44/306 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs769195145; called by muse, mutect2, varscan2
- CDH9 | c.290C>A p.A97D | Missense Mutation (SNP) | VAF 75/153 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50367579; called by muse, mutect2, varscan2
- CELSR2 | c.7591G>A p.V2531I | Missense Mutation (SNP) | VAF 84/196 reads (43%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.47); catalogued as rs192472023; called by muse, mutect2, varscan2
- DNAJC7 | c.514G>C p.A172P | Missense Mutation (SNP) | VAF 117/375 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57270418; called by muse, mutect2, varscan2
- GCN1 | c.7666G>A p.V2556I | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as rs200903918; called by muse, mutect2, varscan2
- GRIK4 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 20/477 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1389864213; called by muse, mutect2
- GRIP1 | c.2429A>T p.D810V (on ENST00000359742 / NM_001379345.1; = p.D758V on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/170 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1156346435; called by muse, mutect2, varscan2
- HINFP | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 105/500 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.859); catalogued as rs963093960; called by muse, mutect2, varscan2
- KANK1 | c.1811G>T p.S604I | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV63214435; called by muse, mutect2, varscan2
- KMT2C | c.6269C>T p.S2090L | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV51469515; called by muse, varscan2
- KMT2C | c.6236C>G p.P2079R | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV51435462; called by muse, varscan2
- LPP | c.1558G>A p.G520R | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); catalogued as rs755218802, COSV100447890; called by muse, varscan2
- MARCHF8 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 56/257 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.771); catalogued as rs75069175; called by muse, mutect2, varscan2
- NEK11 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs368227653; called by muse, mutect2, varscan2
- OR6Q1 | c.543C>A p.F181L | Missense Mutation (SNP) | VAF 71/489 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56932988; called by muse, mutect2, varscan2
- PDE1A | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs770985972, COSV59515206; called by muse, mutect2, varscan2
- PDZRN3 | c.3154G>T p.D1052Y | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV55200910; called by muse, mutect2, varscan2
- PRRC2A | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 64/317 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as rs115229219; called by muse, mutect2, varscan2
- SLC12A5 | c.2045G>A p.R682H (on ENST00000454036 / NM_001134771.2; = p.R659H on NM_020708.5) | Missense Mutation (SNP) | VAF 81/229 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as rs1346179009; called by muse, mutect2, varscan2
- SMAD4 | c.379T>G p.C127G | Missense Mutation (SNP) | VAF 146/257 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61688583, COSV61689297; called by muse, mutect2, varscan2
- SYN3 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 53/421 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138124088; called by muse, mutect2, varscan2
- TMEM198 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 241/716 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as rs758782842; called by muse, mutect2, varscan2
- TP53 | c.414del p.K139Rfs*31 | Frame Shift Del (DEL) | VAF 151/307 reads (49%) | catalogued as rs137852794, COSV52677977; ClinVar: not provided; called by mutect2, pindel, varscan2
- TP73 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 64/418 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs369342367; called by muse, mutect2, varscan2
- TRAPPC9 | c.3277G>A p.A1093T | Missense Mutation (SNP) | VAF 362/1076 reads (34%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs755892862; called by muse, mutect2, varscan2
- ABCD3 | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- ADGRB3 | c.3812A>T p.K1271I | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- AGGF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 82/438 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CDH9 | c.1575dup p.E526* | Frame Shift Ins (INS) | VAF 20/106 reads (19%) | called by mutect2, pindel, varscan2
- CDKN2A | c.259_276del p.R87_D92del | In Frame Del (DEL) | VAF 227/697 reads (33%) | called by mutect2, pindel, varscan2
- CNBD2 | c.671A>T p.D224V | Missense Mutation (SNP) | VAF 116/364 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- CNR1 | c.1291T>G p.C431G | Missense Mutation (SNP) | VAF 106/446 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIAPH2 | c.1061T>C p.L354P | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HCFC1 | c.4210G>A p.G1404S | Missense Mutation (SNP) | VAF 149/304 reads (49%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDLBP | c.2305A>G p.K769E | Missense Mutation (SNP) | VAF 194/667 reads (29%) | SIFT tolerated (0.97); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNH1 | c.1933G>C p.G645R (on ENST00000271751 / NM_172362.3; = p.G618R on NM_002238.4) | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KMT2C | c.6166C>A p.P2056T | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KMT2D | c.11967del p.Q3989Hfs*33 | Frame Shift Del (DEL) | VAF 434/1155 reads (38%) | called by mutect2, pindel, varscan2
- LCA5 | c.1966G>A p.G656S | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MUC16 | c.31535C>T p.S10512L | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NCR3 | c.221_237del p.R74Tfs*9 | Frame Shift Del (DEL) | VAF 91/432 reads (21%) | called by mutect2, pindel, varscan2
- PKHD1L1 | c.9614A>T p.D3205V | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- SCN9A | c.231C>A p.D77E | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); called by muse, varscan2
- ZNF746 | c.1101_1113del p.P368Gfs*20 | Frame Shift Del (DEL) | VAF 32/366 reads (9%) | called by mutect2, pindel
- AGPAT3 | c.660G>A p.G220= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as rs1457079109; called by muse, mutect2, varscan2
- AGPAT3 | c.726G>A p.G242= | Silent (SNP) | VAF 30/264 reads (11%) | called by muse, mutect2, varscan2
- COL6A3 | c.1209G>A p.P403= | Silent (SNP) | VAF 196/573 reads (34%) | catalogued as rs373903065; called by muse, mutect2, varscan2
- DOCK9 | c.927C>T p.S309= (on ENST00000376460 / NM_001366676.2; = p.S310= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 68/208 reads (33%) | catalogued as rs755362899, COSV59645839; called by muse, mutect2, varscan2
- HOGA1 | c.216C>T p.F72= | Silent (SNP) | VAF 206/516 reads (40%) | catalogued as rs780606715, COSV65706601; ClinVar: likely benign; called by muse, mutect2, varscan2
- KLHL18 | c.1332C>T p.F444= | Silent (SNP) | VAF 86/239 reads (36%) | called by muse, mutect2, varscan2
- PSAP | c.501G>A p.V167= | Silent (SNP) | VAF 182/469 reads (39%) | called by muse, mutect2, varscan2
- RALA | c.72C>T p.G24= | Silent (SNP) | VAF 42/340 reads (12%) | catalogued as rs776867160, COSV50050565; called by muse, mutect2, varscan2
- ST8SIA6 | c.204A>G p.T68= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as rs751309814; called by muse, mutect2, varscan2
- TANC2 | c.3531C>T p.G1177= | Silent (SNP) | VAF 23/135 reads (17%) | catalogued as rs760915681; called by muse, mutect2
- TGFA | c.192G>T p.V64= | Silent (SNP) | VAF 96/255 reads (38%) | called by muse, mutect2, varscan2
- AC090151.1 | chr8:54701589 G>A | 3'Flank (SNP) | VAF 40/402 reads (10%) | catalogued as rs915217188; called by muse, mutect2, varscan2
- CHRNA4 | c.*3250G>C | 3'UTR (SNP) | VAF 359/944 reads (38%) | called by muse, mutect2, varscan2
- DMAC2 | chr19:41439914 G>A | 5'Flank (SNP) | VAF 64/221 reads (29%) | called by muse, mutect2, varscan2
- GLRX2 | chr1:193105519 C>G | 5'Flank (SNP) | VAF 37/152 reads (24%) | called by muse, mutect2, varscan2
- GRN | c.138+34G>T | Intron (SNP) | VAF 338/570 reads (59%) | called by muse, mutect2, varscan2
- MTRNR2L8 | c.-8T>C | 5'UTR (SNP) | VAF 218/314 reads (69%) | catalogued as rs7350541, COSV56417119; called by mutect2, varscan2
- MUC2 | chr11:1094568 T>C | 3'Flank (SNP) | VAF 8/72 reads (11%) | catalogued as rs199927035; called by muse, varscan2
- OR2L1P | n.883C>G | RNA (SNP) | VAF 39/340 reads (11%) | called by muse, mutect2, varscan2
- RIPPLY2 | c.95+56C>T | Intron (SNP) | VAF 47/158 reads (30%) | called by muse, mutect2, varscan2
- SPDYE1 | chr7:44013611 G>T | 3'Flank (SNP) | VAF 39/389 reads (10%) | called by muse, mutect2
- SUCO | c.-206_-198del | 5'UTR (DEL) | VAF 86/249 reads (35%) | called by mutect2, pindel, varscan2
